RC case RC-B6SE — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5ae3d7f5-617d-4741-904c-9d5d738c1b08

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Year of birth: 1956; Vital status: Alive.

Diagnoses (2)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of axilla or arm; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 58.3 years (21,302 days); Year of diagnosis: 2015; Method of diagnosis: Excisional Biopsy; Prior malignancy: yes; Synchronous malignancy: No; International Prognostic Index (IPI): Low Risk.
   Pathology details: Bone marrow malignant cells: No; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ICE; Days to treatment start: 34 days; Days to treatment end: 174 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP; Days to treatment start: 34 days; Days to treatment end: 174 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 174 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Recorded as not given: Stem Cell Transplantation, Allogeneic.
2. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 50.7 years (18,503 days); Year of diagnosis: 2007; Days to diagnosis: -2,799 days (-7.7 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,799 days (-7.7 years); Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 73 days; Disease response: Partial Response.
- Day 170 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Follow-up contact recording only the day: day 2,338.

Molecular and laboratory tests
- Lactate Dehydrogenase 702 U/L [Blood test normal range upper: 618].

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SE-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SE-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SE-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 2.
